Somatic mutation profile of tumor specimen TCGA-SL-A6JA-01A (aliquot TCGA-SL-A6JA-01A-11D-A31U-09) from TCGA case TCGA-SL-A6JA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 77.8 years (28,401 days).
Specimen TCGA-SL-A6JA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ed7fe70-38e4-410a-928d-b1ee699afe02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SL-A6JA-10A (Blood Derived Normal), aliquot TCGA-SL-A6JA-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46ba17ce-be12-4a21-83fc-347bcfdcbb86

The open-access MAF lists 915 somatic variants for this specimen: 697 protein-altering or splice-affecting, 197 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 421, Silent 197, Frame Shift Del 172, Nonsense Mutation 38, Frame Shift Ins 37, Splice Site 13, Intron 11, In Frame Del 9, Splice Region 7, 3'UTR 5, 3'Flank 2, RNA 2.

Variants (750 of 915; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL9A1 | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as rs189754995, CM116926, COSV100295180, COSV57888458; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CWC27 | c.1002del p.V335* | Frame Shift Del (DEL) | VAF 17/34 reads (50%) | catalogued as rs752159903; ClinVar: pathogenic; called by mutect2, varscan2
- EYS | c.179del p.L60Wfs*3 | Frame Shift Del (DEL) | VAF 15/30 reads (50%) | catalogued as rs786205652, CD157904; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MMAB | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746219370, CM061120, COSV99904582; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.3328del p.I1110Lfs*16 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs770866403; ClinVar: likely pathogenic; called by mutect2, varscan2
- SERPINA1 | c.1158dup p.E387Rfs*14 | Frame Shift Ins (INS) | VAF 16/34 reads (47%) | catalogued as rs764325655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SF3B4 | c.1060dup p.R354Pfs*132 | Frame Shift Ins (INS) | VAF 29/74 reads (39%) | catalogued as rs782357237; ClinVar: pathogenic; called by mutect2, varscan2
- TSC1 | c.1257dup p.R420Qfs*22 | Frame Shift Ins (INS) | VAF 24/53 reads (45%) | catalogued as rs118203506, COSV53767785; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- ABCA3 | c.2512C>T p.R838W | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773021659, COSV100068867; called by muse, mutect2, varscan2
- ABCC1 | c.1763T>A p.L588* | Nonsense Mutation (SNP) | VAF 25/48 reads (52%) | catalogued as rs1567367683, COSV100579973; called by muse, mutect2, varscan2
- ABCC11 | c.3317C>T p.T1106M | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs139677111; called by muse, varscan2
- ABCC3 | c.836del p.N279Mfs*22 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as COSV99558824; called by mutect2, pindel, varscan2
- AC109583.1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs147459039; called by muse, mutect2
- ACTRT2 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs150794947, COSV65760423; called by muse, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM28 | c.1790T>C p.I597T | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.739); catalogued as rs1462551050, COSV99739253; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022dup p.N342Efs*2 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS14 | c.408G>A p.W136* | Nonsense Mutation (SNP) | VAF 12/19 reads (63%) | catalogued as COSV100941730; called by muse, mutect2, varscan2
- ADAP1 | c.971G>A p.G324D | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99763226; called by muse, mutect2, varscan2
- ADAR | c.2788T>C p.Y930H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV99426374; called by muse, mutect2, varscan2
- ADCY6 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57167753; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs760140619; called by mutect2, varscan2
- ADH1C | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423604859, COSV101565191; called by muse, mutect2, varscan2
- ADSL | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs864309550, COSV53409066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFF1 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.111); catalogued as rs761156221, COSV100320874; called by muse, mutect2, varscan2
- AGPS | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99931550; called by muse, mutect2, varscan2
- AHNAK | c.9529G>A p.A3177T | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV99948532; called by muse, mutect2
- AHNAK2 | c.9371G>A p.R3124Q | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT tolerated, low confidence (0.81); PolyPhen possibly damaging (0.633); catalogued as rs764799404, COSV100318291; called by muse, mutect2, varscan2
- AIMP2 | c.327T>A p.N109K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV99774074; called by muse, mutect2, varscan2
- AKAP9 | c.5567G>A p.R1856Q (on ENST00000359028; = p.R1824Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.123); catalogued as rs970122684, COSV100662710; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 46/92 reads (50%) | catalogued as COSV101202416, COSV66573157; called by muse, mutect2, varscan2
- AMHR2 | c.967+1G>A p.X323_splice | Splice Site (SNP) | VAF 13/30 reads (43%) | catalogued as COSV99143389; called by muse, mutect2, varscan2
- ANAPC1 | c.5202G>T p.K1734N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100594928, COSV61975722; called by muse, mutect2, varscan2
- ANKRD44 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs377194538; called by muse, mutect2, varscan2
- ANKRD50 | c.3502C>T p.P1168S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV101539000; called by muse, mutect2, varscan2
- ANKS4B | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1043739002, COSV100289775; called by muse, mutect2, varscan2
- AP2A1 | c.2632C>T p.R878C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58241276; called by muse, mutect2
- ARFGEF1 | c.4373C>T p.A1458V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99143369; called by muse, mutect2, varscan2
- ARHGAP39 | c.1621G>T p.G541C | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV99431805; called by muse, mutect2, varscan2
- ARHGEF1 | c.1748C>A p.T583K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV100529100; called by muse, mutect2, varscan2
- ARHGEF10L | c.3533G>A p.R1178H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.045); catalogued as rs368787002, COSV99393376; called by muse, mutect2, varscan2
- ARID1A | c.4604C>T p.T1535I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.527); catalogued as COSV100252508; called by muse, mutect2, varscan2
- ARRDC2 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as rs761043664, COSV99716698; called by muse, mutect2, varscan2
- ARSD | c.1661C>A p.T554N | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV101144581; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs761154268; called by mutect2, varscan2
- ASH1L | c.3814C>T p.R1272W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs750816124, COSV64206961; called by muse, mutect2, varscan2
- ASPHD1 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs758545223, COSV100435636; called by muse, mutect2, varscan2
- ATL1 | c.1111del p.M371Wfs*29 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | catalogued as rs1566733927; called by mutect2, pindel, varscan2
- ATL3 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100219929; called by muse, mutect2, varscan2
- ATPSCKMT | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1437374941, COSV54726743; called by muse, mutect2, varscan2
- B3GNT8 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54198707, COSV99524685; called by muse, mutect2, varscan2
- BBS5 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 47/77 reads (61%) | catalogued as COSV99752080; called by muse, mutect2, varscan2
- BCOR | c.3148G>A p.D1050N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1318747465, COSV60721012; called by muse, mutect2, varscan2
- BCS1L | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1339202901, COSV99829114; called by muse, mutect2, varscan2
- BEX5 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs143243676, COSV100375066; called by muse, mutect2, varscan2
- BICC1 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1298181941, COSV100874882; called by mutect2, varscan2
- BLVRB | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as rs549377727, COSV99648010; called by muse, mutect2, varscan2
- BMP7 | c.350dup p.L118Sfs*7 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as COSV104431177; called by pindel, varscan2
- BPTF | c.1049A>C p.E350A | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV100075463; called by muse, mutect2, varscan2
- BSN | c.7682G>A p.R2561H | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753587578, COSV99609140; called by muse, mutect2, varscan2
- C10orf71 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs183879740, COSV100110414, COSV60505553; called by muse, mutect2, varscan2
- C2orf42 | c.1708A>G p.T570A | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV100034046; called by muse, mutect2, varscan2
- CA11 | c.760C>A p.L254I | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.194); catalogued as COSV50032827, COSV99320737; called by muse, mutect2, varscan2
- CACNA1B | c.5906G>A p.G1969E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.416); catalogued as COSV99498564; called by muse, mutect2, varscan2
- CACNA1C | c.88A>G p.M30V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.007); catalogued as rs1367916633, COSV100220383; called by muse, mutect2, varscan2
- CACNA1F | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.701); catalogued as COSV100545133; called by muse, mutect2, varscan2
- CALML3 | c.217A>G p.M73V | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.061); catalogued as COSV100178860; called by muse, mutect2, varscan2
- CASZ1 | c.4552C>A p.L1518M | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV100985653; called by muse, mutect2, varscan2
- CATSPERG | c.1196-1G>A p.X399_splice | Splice Site (SNP) | VAF 26/51 reads (51%) | catalogued as COSV99286734; called by muse, mutect2, varscan2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 31/73 reads (42%) | catalogued as rs756536005; called by mutect2, pindel, varscan2
- CCAR2 | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.36); PolyPhen benign (0.046); catalogued as COSV99374196; called by muse, mutect2, varscan2
- CCDC153 | c.599dup p.G201Wfs*9 | Frame Shift Ins (INS) | VAF 7/26 reads (27%) | catalogued as rs745729530; called by mutect2, varscan2
- CCDC181 | c.1265dup p.H423Afs*24 (on ENST00000367806 / NM_001300969.1; = p.H422Afs*24 on NM_021179.2) | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC183 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1463586517, COSV61033475; called by mutect2, varscan2
- CCDC42 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as rs538010989, COSV53450000; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC43 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as rs748154015, COSV59520005; called by muse, mutect2, varscan2
- CCNB2 | c.841G>T p.V281F | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.544); catalogued as COSV99879118; called by muse, mutect2, varscan2
- CCPG1 | c.1846C>A p.H616N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.074); catalogued as COSV51241516, COSV99380542; called by muse, mutect2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 52/98 reads (53%) | catalogued as rs762805003; called by mutect2, varscan2
- CDH13 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as rs377210458, CM112950; called by muse, mutect2, varscan2
- CDH20 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1427688843, COSV99405962; called by muse, mutect2, varscan2
- CDH4 | c.1781del p.P594Rfs*35 | Frame Shift Del (DEL) | VAF 15/28 reads (54%) | catalogued as rs1367432489; called by mutect2, pindel, varscan2
- CDK9 | c.627dup p.I210Hfs*2 | Frame Shift Ins (INS) | VAF 8/18 reads (44%) | catalogued as rs755440676; called by mutect2, varscan2
- CEACAM1 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs773342137, COSV99362466; called by muse, mutect2, varscan2
- CEACAM18 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as rs371813587; called by muse, mutect2, varscan2
- CECR2 | c.3266_3267insT p.K1089Nfs*5 (on ENST00000342247 / NM_001290047.2; = p.K905Nfs*5 on NM_001290046.1) | Frame Shift Ins (INS) | VAF 9/22 reads (41%) | catalogued as COSV99378633; called by mutect2, pindel, varscan2
- CENPF | c.8593T>C p.C2865R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100871818; called by muse, mutect2, varscan2
- CFP | c.75A>G p.T25= | Splice Region (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99901592; called by muse, mutect2, varscan2
- CHAC2 | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as COSV99712267; called by muse, mutect2, varscan2
- CHD6 | c.2582C>T p.A861V | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1274369410, COSV100498257; called by muse, mutect2, varscan2
- CHERP | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs543141111, COSV99550385; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs751548647; called by mutect2, varscan2
- CIT | c.4066C>T p.R1356C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1411407183, COSV99950338; called by muse, mutect2, varscan2
- CLASP1 | c.3296C>T p.T1099M | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs746640653, COSV99756023; called by muse, mutect2, varscan2
- CLCN2 | c.1142del p.P381Lfs*35 | Frame Shift Del (DEL) | VAF 25/65 reads (38%) | catalogued as rs1217596296; called by mutect2, pindel, varscan2
- CLDN5 | c.59dup p.L21Sfs*232 (on ENST00000618236 / NM_001363066.2; = p.L106Sfs*232 on NM_003277.4) | Frame Shift Ins (INS) | VAF 12/22 reads (55%) | catalogued as rs768198935; called by mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs369752219; called by mutect2, varscan2
- CLUH | c.2773C>T p.Q925* (on ENST00000435359; = p.Q964* on NM_015229.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV101425821; called by muse, mutect2, varscan2
- CLUH | c.976del p.Q326Rfs*80 (on ENST00000435359; = p.Q364Rfs*80 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | catalogued as rs1418382371; called by mutect2, pindel, varscan2
- CNTNAP2 | c.1083+1G>A p.X361_splice | Splice Site (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100668595; called by muse, mutect2, varscan2
- CNTNAP2 | c.1327A>G p.S443G | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.079); catalogued as COSV100668596; called by muse, mutect2, varscan2
- CNTNAP3 | c.3082G>A p.V1028I | Missense Mutation (SNP) | VAF 97/917 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1368677445; called by muse, mutect2
- CNTNAP5 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs1040705347, COSV70477432; called by muse, mutect2, varscan2
- COL26A1 | c.757G>A p.G253S (on ENST00000313669 / NM_001278563.3; = p.G251S on NM_133457.4) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373938643; called by muse, mutect2, varscan2
- COL3A1 | c.2552C>T p.A851V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100483419; called by muse, mutect2, varscan2
- COL6A6 | c.1240A>G p.T414A | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV100650002, COSV100650601; called by muse, mutect2, varscan2
- COL6A6 | c.5725G>A p.A1909T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs953900662, COSV100650603; called by muse, mutect2
- CPLANE1 | c.8171A>T p.D2724V | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99951144; called by muse, mutect2, varscan2
- CPNE8 | c.433A>G p.T145A | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100504824; called by muse, mutect2, varscan2
- CRAT | c.495del p.K166Sfs*5 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | catalogued as rs772054700, COSV58879005; called by mutect2, pindel, varscan2
- CRYGN | c.169T>C p.F57L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.216); catalogued as COSV100484777; called by muse, mutect2, varscan2
- CST2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100491265; called by muse, mutect2
- CTDSPL | c.524C>T p.A175V (on ENST00000273179 / NM_001008392.2; = p.A164V on NM_005808.3) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99828871; called by muse, mutect2, varscan2
- CTSZ | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs201081854; called by muse, mutect2, varscan2
- CUL4A | c.313C>T p.Q105* (on ENST00000375440 / NM_001008895.4; = p.Q5* on NM_003589.3) | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV100417417; called by muse, mutect2, varscan2
- CXADR | c.398T>G p.I133S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV99515514; called by muse, mutect2, varscan2
- CXXC1 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.677); catalogued as rs753825708, COSV99496788; called by muse, mutect2, varscan2
- CYP2C8 | c.349G>T p.G117* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100987984; called by muse, mutect2, varscan2
- CYP2S1 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100027533; called by muse, mutect2, varscan2
- CYP4F2 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as rs770633305, COSV55616064; called by muse, mutect2
- DAG1 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs143573515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCAF6 | c.2156C>A p.S719Y (on ENST00000312263 / NM_001349778.1; = p.S739Y on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100394531; called by muse, mutect2, varscan2
- DCLRE1A | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100800428; called by muse, mutect2, varscan2
- DDX27 | c.1869G>A p.M623I | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100873418, COSV65609783; called by muse, mutect2, varscan2
- DDX3X | c.806T>A p.L269* (on ENST00000399959; = p.L270* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV101302480; called by muse, mutect2, varscan2
- DENND1B | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.249); catalogued as rs140388741; called by muse, mutect2, varscan2
- DGKE | c.850G>T p.G284W | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401096; called by muse, mutect2, varscan2
- DGKI | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.691); catalogued as rs148415050; called by muse, mutect2, varscan2
- DHRS7C | c.569C>T p.T190M (on ENST00000330255 / NM_001220493.2; = p.T189M on NM_001105571.3) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs374278019; called by muse, mutect2, varscan2
- DLEC1 | c.3373C>T p.R1125W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs558780034, COSV100342972; called by muse, mutect2
- DLGAP3 | c.1207del p.D403Mfs*65 | Frame Shift Del (DEL) | VAF 30/67 reads (45%) | catalogued as COSV52396810; called by mutect2, pindel, varscan2
- DNAH10 | c.9424G>A p.A3142T (on ENST00000409039; = p.A3081T on NM_207437.3) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as rs1246358575, COSV101292454; called by muse, mutect2, varscan2
- DNAH11 | c.4669C>T p.R1557* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as rs759040005, COSV60977824; called by muse, mutect2, varscan2
- DNAH11 | c.5399T>C p.M1800T | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV60950633; called by muse, mutect2, varscan2
- DNHD1 | c.13127T>C p.M4376T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV99600589; called by muse, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DRAP1 | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.205); catalogued as COSV100437136; called by muse, mutect2, varscan2
- DRD2 | c.1103A>G p.E368G | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100669889; called by muse, mutect2
- DUSP4 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs919580482, COSV99529934; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 17/29 reads (59%) | catalogued as rs755197346; called by mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs772082432; called by mutect2, varscan2
- DYNC2H1 | c.10961A>T p.N3654I | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV100519120; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.140_142del p.S47del | In Frame Del (DEL) | VAF 32/75 reads (43%) | catalogued as rs776345863; called by pindel, varscan2
- EEF2K | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99533388; called by muse, mutect2, varscan2
- EFCAB13 | c.1024del p.S342Afs*25 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs759569556; called by mutect2, pindel, varscan2
- EGFR | c.2555A>C p.K852T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51800018, COSV99293220; called by muse, mutect2, varscan2
- EID2 | c.454A>G p.N152D | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV66811111; called by muse, mutect2, varscan2
- EIF4E1B | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867316543, COSV100024801; called by mutect2, varscan2
- ELP4 | c.950G>A p.R317H (on ENST00000350638; = p.R316H on NM_019040.5) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs749842817, COSV63355256; called by muse, mutect2, varscan2
- EML3 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs559133378, COSV99606018; called by muse, mutect2, varscan2
- ENPP7 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs369179109; called by muse, mutect2
- EPB41L4A | c.493T>C p.F165L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.698); catalogued as COSV99813302, COSV99813754; called by muse, mutect2, varscan2
- EPHA1 | c.151-1G>A p.X51_splice | Splice Site (SNP) | VAF 11/18 reads (61%) | catalogued as rs935517892, COSV51976778; called by muse, mutect2, varscan2
- EPHB3 | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs747285934, COSV57807641, COSV57808210; called by muse, mutect2, varscan2
- EPN2 | c.1408del p.T470Qfs*5 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs756461692; called by mutect2, varscan2
- ERBB4 | c.3238C>T p.P1080S | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.42); PolyPhen benign (0.049); catalogued as COSV61482928; called by muse, mutect2, varscan2
- ESPL1 | c.3679T>C p.Y1227H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV99229536; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs775950025; called by mutect2, varscan2
- ESYT1 | c.2278C>T p.R760C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs749573194, COSV99920125; called by muse, mutect2, varscan2
- ETV1 | c.414del p.T139Hfs*116 | Frame Shift Del (DEL) | VAF 18/41 reads (44%) | catalogued as COSV54136078; called by mutect2, pindel, varscan2
- EVI5L | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99563359; called by muse, mutect2, varscan2
- FAM114A1 | c.776C>A p.T259N | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.976); catalogued as COSV100729397; called by muse, mutect2, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM217B | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as rs760313441, COSV100674591, COSV100674597; called by muse, varscan2
- FANCE | c.929del p.P310Qfs*54 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, pindel, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 9/18 reads (50%) | catalogued as rs746983128; called by mutect2, varscan2
- FAT1 | c.9229G>T p.G3077C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101499469; called by muse, mutect2, varscan2
- FBXO21 | c.1653T>A p.Y551* (on ENST00000330622 / NM_033624.3; = p.Y544* on NM_015002.3) | Nonsense Mutation (SNP) | VAF 26/59 reads (44%) | catalogued as COSV100401812; called by muse, mutect2, varscan2
- FBXO46 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs984787955, COSV58349569; called by muse, mutect2, varscan2
- FCN1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs756646348, COSV65662353; called by muse, mutect2, varscan2
- FER1L6 | c.4660C>T p.P1554S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.629); catalogued as COSV101206073; called by muse, mutect2, varscan2
- FFAR2 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs201383852; called by muse, mutect2, varscan2
- FGF18 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99209495; called by muse, mutect2, varscan2
- FGF8 | c.413G>T p.S138I (on ENST00000344255 / NM_033164.4; = p.S120I on NM_006119.6) | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV100199407; called by muse, mutect2, varscan2
- FIBCD1 | c.1324G>A p.G442S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1429295208, COSV53395996; called by muse, mutect2, varscan2
- FKBP15 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.491); catalogued as COSV99439318; called by muse, mutect2, varscan2
- FKRP | c.1337T>C p.L446P | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100586709; called by muse, mutect2, varscan2
- FLG | c.4141G>T p.A1381S | Missense Mutation (SNP) | VAF 71/268 reads (26%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.482); catalogued as rs1557878034, COSV100911845; called by muse, mutect2, varscan2
- FLNA | c.5488G>A p.V1830M (on ENST00000369850 / NM_001110556.2; = p.V1822M on NM_001456.3) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs782505945, COSV61037963; called by muse, varscan2
- FLT4 | c.89dup p.T31Dfs*15 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | catalogued as rs755445139; called by mutect2, varscan2
- FNTB | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs376882084; called by muse, mutect2, varscan2
- FOXK1 | c.1555G>C p.A519P | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100195512; called by muse, mutect2, varscan2
- FOXRED2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1439143957, COSV53401042; called by muse, mutect2, varscan2
- FRAS1 | c.6961C>T p.R2321W | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as rs757956184, COSV53635947; called by muse, mutect2, varscan2
- FRMPD3 | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs752252029, COSV52185944; called by muse, mutect2, varscan2
- FRYL | c.1645del p.E549Kfs*19 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as COSV51962239; called by mutect2, pindel, varscan2
- FYCO1 | c.3596G>A p.G1199D | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99945954; called by muse, mutect2, varscan2
- FZD10 | c.635C>T p.T212M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.416); catalogued as COSV57475777; called by muse, mutect2
- GABRG2 | c.764G>A p.R255H (on ENST00000361925 / NM_001375343.1; = p.R215H on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV62715550; called by muse, mutect2, varscan2
- GANC | c.2575_2577del p.E859del | In Frame Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs1243891315; called by mutect2, pindel, varscan2
- GCNA | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV101031685; called by muse, mutect2, varscan2
- GCNT4 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100466535; called by muse, mutect2
- GET1 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV100414419; called by muse, mutect2, varscan2
- GFAP | c.522+1G>A p.X174_splice | Splice Site (SNP) | VAF 27/65 reads (42%) | catalogued as rs1250595736, COSV99493477; called by muse, mutect2, varscan2
- GGTLC2 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101312247; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 15/30 reads (50%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GMCL1 | c.1478G>A p.S493N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV99247850; called by muse, mutect2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 16/37 reads (43%) | catalogued as rs763679060; called by mutect2, varscan2
- GOLGA6A | c.151del p.T51Lfs*24 | Frame Shift Del (DEL) | VAF 25/181 reads (14%) | catalogued as rs764754072; called by mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 38/73 reads (52%) | catalogued as rs1416935976; called by mutect2, varscan2
- GRINA | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs376323488; called by muse, mutect2, varscan2
- H4C6 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.338); catalogued as COSV100897499; called by muse, mutect2, varscan2
- HAUS1 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as rs749832789, COSV99959528; called by muse, mutect2, varscan2
- HBS1L | c.1984C>A p.L662M | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100892631; called by muse, mutect2, varscan2
- HDLBP | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs760239912, COSV100191325; called by muse, mutect2, varscan2
- HERC2 | c.10952G>A p.R3651H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757141755, COSV55339684; called by muse, mutect2, varscan2
- HIP1R | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1012332938, COSV99459080; called by muse, mutect2, varscan2
- HIPK4 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs763886506, COSV99396657; called by muse, mutect2, varscan2
- HLA-DMB | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 37/83 reads (45%) | catalogued as rs1210603131, COSV101186844; called by muse, mutect2, varscan2
- HMGN4 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV101110245; called by muse, mutect2, varscan2
- HNRNPL | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99670446; called by muse, mutect2, varscan2
- HOOK3 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs143640988; called by muse, mutect2, varscan2
- HOXC4 | c.488A>T p.Y163F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100324294; called by muse, mutect2, varscan2
- HPCAL4 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100864803; called by muse, mutect2
- HRG | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as rs370685538; called by muse, mutect2
- HSPB8 | c.266dup p.P90Tfs*37 | Frame Shift Ins (INS) | VAF 11/23 reads (48%) | catalogued as rs773017653; called by mutect2, varscan2
- HYKK | c.643T>A p.L215I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.135); catalogued as COSV101195091; called by muse, mutect2, varscan2
- IGHV1-69 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs368394268; called by mutect2, varscan2
- IGLV3-16 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | catalogued as rs746629447; called by mutect2, pindel, varscan2
- IGSF9B | c.439dup p.Q147Pfs*10 | Frame Shift Ins (INS) | VAF 16/33 reads (48%) | catalogued as rs748943611; called by mutect2, varscan2
- IL12RB1 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs201223132, COSV59095934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IMPDH1 | c.961C>T p.R321C (on ENST00000470772 / NM_001142573.2; = p.R407C on NM_000883.4) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as rs758941308, COSV100118743; called by muse, mutect2, varscan2
- INHBC | c.9_11del p.S4del | In Frame Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs773839607; called by pindel, varscan2
- IQGAP3 | c.63G>T p.M21I | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100752227; called by muse, mutect2, varscan2
- IRX5 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV100315894; called by muse, mutect2, varscan2
- ISM1 | c.579del p.R194Gfs*82 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | catalogued as rs762230866, COSV99339624; called by mutect2, varscan2
- ITIH3 | c.2582G>A p.G861D | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99819642; called by muse, mutect2, varscan2
- JAKMIP3 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761693157, COSV53826361; called by muse, mutect2, varscan2
- JMJD8 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as rs750654939, COSV99555880; called by muse, mutect2, varscan2
- JMY | c.2104C>T p.R702* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as rs1349756551, COSV68660803, COSV68662092; called by muse, mutect2, varscan2
- KALRN | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.202); catalogued as COSV99565906; called by muse, mutect2, varscan2
- KALRN | c.4204G>A p.G1402S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV53773916; called by muse, mutect2, varscan2
- KANSL2 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as COSV100771016; called by muse, mutect2, varscan2
- KCNH8 | c.1244del p.P415Rfs*15 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as COSV60466332; called by mutect2, pindel, varscan2
- KCNQ5 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as COSV100572526; called by muse, mutect2, varscan2
- KCTD3 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); catalogued as COSV99379502; called by muse, mutect2, varscan2
- KCTD3 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52065950, COSV52066457; called by muse, mutect2, varscan2
- KDM6B | c.4825C>T p.R1609C | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV99641921; called by muse, varscan2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 20/41 reads (49%) | catalogued as rs749990720; called by mutect2, varscan2
- KIDINS220 | c.1953G>A p.W651* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99876097, COSV99876315; called by muse, mutect2, varscan2
- KIF14 | c.532T>G p.S178A | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100950973; called by muse, mutect2, varscan2
- KIR3DL1 | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1418339927; called by muse, mutect2, varscan2
- KIRREL3 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 39/81 reads (48%) | catalogued as COSV101585572; called by muse, mutect2, varscan2
- KLHL4 | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs746712371, COSV100910016; called by muse, mutect2, varscan2
- KMT2B | c.5263C>T p.P1755S | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55869730; called by muse, mutect2, varscan2
- KMT2B | c.6336A>C p.E2112D | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV99720109; called by muse, mutect2, varscan2
- KMT2B | c.7463A>G p.Y2488C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99720110; called by muse, mutect2, varscan2
- KMT2D | c.10744C>T p.R3582W | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56491153; called by muse, mutect2, varscan2
- KPNA2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs1555704877, COSV57857456, COSV57858876; called by muse, mutect2, varscan2
- KPNA2 | c.1472T>C p.L491S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100388830; called by muse, mutect2, varscan2
- KRT1 | c.1642G>A p.G548S | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.937); catalogued as rs775570636, COSV99358900; called by muse, mutect2, varscan2
- KRT83 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1194656235, COSV53340254; called by muse, mutect2, varscan2
- KRTAP5-3 | c.350C>A p.S117Y | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV101294518; called by muse, mutect2, varscan2
- LAMA3 | c.3362T>C p.V1121A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100557209; called by muse, mutect2, varscan2
- LAP3 | c.342G>A p.W114* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99884441; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LAT | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100209040, COSV57956765; called by muse, mutect2, varscan2
- LENG9 | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100002875; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 33/66 reads (50%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMNB1 | c.1403G>A p.G468D | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99746085; called by muse, mutect2, varscan2
- LPCAT3 | c.1126C>A p.L376M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99781220; called by muse, mutect2, varscan2
- LPCAT4 | c.1469dup p.H491Tfs*75 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs766365810; called by mutect2, pindel, varscan2
- LRP1 | c.4268G>A p.R1423H | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777476570, COSV54515929; called by muse, mutect2, varscan2
- LRP1B | c.5272A>C p.N1758H | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV67254988; called by muse, mutect2, varscan2
- LRRC4 | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as COSV99975123; called by muse, mutect2, varscan2
- LRRK1 | c.28A>C p.S10R | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99441605; called by muse, mutect2, varscan2
- LRRK2 | c.4915del p.R1639Gfs*15 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | catalogued as rs756089224; called by mutect2, varscan2
- LRRN2 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs774495531, COSV65784203; called by muse, varscan2
- LTBP3 | c.1712A>G p.Q571R | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100099981; called by muse, mutect2, varscan2
- MAGEB10 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV100775333, COSV100775336; called by muse, mutect2, varscan2
- MAP2K3 | c.124del p.R42Gfs*24 (on ENST00000342679 / NM_145109.3; = p.R13Gfs*24 on NM_002756.4) | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | catalogued as rs1567665648, COSV57561353; called by mutect2, pindel, varscan2
- MAP7D3 | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100286515; called by muse, mutect2, varscan2
- MAPK3 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV99531812; called by muse, mutect2, varscan2
- MARF1 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1016527357, COSV100706126; called by muse, mutect2, varscan2
- MCHR2 | c.309del p.P104Lfs*21 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | catalogued as rs902197100; called by mutect2, pindel, varscan2
- MCTP1 | c.1592_1594del p.G531del | In Frame Del (DEL) | VAF 26/66 reads (39%) | catalogued as rs749032818; called by pindel, varscan2
- MEGF6 | c.4318dup p.A1440Gfs*4 | Frame Shift Ins (INS) | VAF 16/32 reads (50%) | catalogued as rs759225724; called by mutect2, varscan2
- METTL25 | c.366A>G p.I122M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs751774509, COSV99942545; called by muse, mutect2, varscan2
- MEX3B | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100314137, COSV61663629; called by muse, mutect2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 30/58 reads (52%) | catalogued as rs780635289; called by mutect2, varscan2
- MMP1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs201865180, COSV100188027; called by muse, mutect2, varscan2
- MNDA | c.876T>A p.N292K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100933398; called by muse, mutect2
- MORF4L2 | c.668A>G p.Y223C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100846387; called by muse, mutect2, varscan2
- MOV10L1 | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV99434436; called by muse, mutect2, varscan2
- MROH5 | c.3808G>A p.V1270M | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as rs547253684, COSV100267368; called by muse, mutect2, varscan2
- MRTFA | c.1220del p.P407Qfs*30 | Frame Shift Del (DEL) | VAF 27/81 reads (33%) | catalogued as rs34028511; called by pindel, varscan2
- MTCL1 | c.2669T>C p.L890P (on ENST00000306329 / NM_001378206.1; = p.L530P on NM_015210.4) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100095176; called by muse, mutect2, varscan2
- MTMR3 | c.2584G>T p.G862C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.417); catalogued as COSV100071102; called by muse, mutect2
- MTREX | c.2039dup p.S681Vfs*4 | Frame Shift Ins (INS) | VAF 16/41 reads (39%) | catalogued as rs1351105989; called by mutect2, pindel, varscan2
- MTSS1 | c.459del p.R155Efs*34 | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | catalogued as rs1563799887; called by mutect2, pindel, varscan2
- MUC5AC | c.969del p.L324Cfs*137 | Frame Shift Del (DEL) | VAF 21/48 reads (44%) | catalogued as rs1227165697; called by mutect2, pindel, varscan2
- MUS81 | c.461G>C p.G154A | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.452); catalogued as COSV100337306, COSV57261400; called by muse, mutect2, varscan2
- MX2 | c.1000A>G p.T334A | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.099); catalogued as COSV100416061; called by muse, mutect2, varscan2
- MYH13 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs1471406082, COSV52837947; called by muse, mutect2, varscan2
- MYH3 | c.4810G>A p.A1604T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.2); catalogued as rs201488879, COSV56864024; called by muse, mutect2, varscan2
- MYH4 | c.2708C>T p.A903V | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV99701768; called by muse, mutect2, varscan2
- MYL12B | c.431G>T p.R144I | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV99410622; called by muse, mutect2, varscan2
- MYO15A | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99233655; called by muse, mutect2, varscan2
- MYOC | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs144709484; called by muse, mutect2, varscan2
- MYOD1 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100000338; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 20/40 reads (50%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- MZF1 | c.451A>G p.S151G | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99285357; called by muse, mutect2, varscan2
- N4BP2 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770639357, COSV54702631, COSV54703786; called by muse, mutect2, varscan2
- NBEA | c.2920A>G p.K974E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.971); catalogued as COSV100082313; called by muse, mutect2, varscan2
- NBEAL2 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV99436757; called by muse, mutect2, varscan2
- NCAPG2 | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99317335; called by muse, mutect2, varscan2
- NCCRP1 | c.339C>T p.G113= | Splice Region (SNP) | VAF 21/45 reads (47%) | catalogued as rs376922857; called by muse, mutect2, varscan2
- NCOR1 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV99246635, COSV99250989; called by muse, mutect2, varscan2
- NECTIN2 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs750364859, COSV52975445; called by muse, mutect2, varscan2
- NEK2 | c.96+1G>A p.X32_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | catalogued as rs773611546, COSV100878699; called by muse, mutect2, varscan2
- NET1 | c.574G>T p.D192Y (on ENST00000355029 / NM_001047160.3; = p.D138Y on NM_005863.5) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100742338; called by muse, mutect2, varscan2
- NFATC3 | c.2068del p.S690Afs*12 | Frame Shift Del (DEL) | VAF 21/34 reads (62%) | catalogued as COSV60473781; called by mutect2, pindel, varscan2
- NFKB2 | c.1681G>T p.D561Y | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99193033; called by muse, mutect2, varscan2
- NIN | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55386372, COSV99814310; called by muse, mutect2, varscan2
- NLGN3 | c.1601C>A p.P534H (on ENST00000358741 / NM_181303.2; = p.P514H on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100704896; called by muse, mutect2, varscan2
- NLRP8 | c.398T>C p.L133S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV99405639; called by muse, mutect2, varscan2
- NOM1 | c.1783G>A p.V595I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs149569042; called by muse, mutect2, varscan2
- NOP58 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV51895456; called by muse, mutect2, varscan2
- NR4A3 | c.95A>G p.N32S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0.138); catalogued as COSV100432584; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 12/21 reads (57%) | catalogued as rs776154715; called by mutect2, varscan2
- NT5DC2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs573448959, COSV58732672; called by muse, mutect2, varscan2
- NTF4 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as rs749392406, COSV100032295; called by muse, mutect2, varscan2
- NUP155 | c.2276T>A p.M759K (on ENST00000231498 / NM_153485.3; = p.M700K on NM_004298.4) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV99193882; called by muse, mutect2, varscan2
- NUP43 | c.639G>A p.L213= | Splice Region (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100462195; called by muse, mutect2, varscan2
- NUTM2A | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.305); catalogued as COSV101095742; called by mutect2, varscan2
- NXPE4 | c.1345C>T p.R449* (on ENST00000375478 / NM_001077639.2; = p.R165* on NM_017678.3) | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as rs750280300, COSV100970298, COSV64943495; called by muse, mutect2, varscan2
- OAZ1 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 18/30 reads (60%) | catalogued as rs1350599044, COSV100457375; called by muse, mutect2, varscan2
- ODF3 | c.171del p.M58Cfs*15 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as COSV100285390; called by mutect2, pindel, varscan2
- OR10J3 | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1436578188, COSV59953941; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 34/132 reads (26%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2C3 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100825742; called by muse, mutect2, varscan2
- OR2H2 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.461); catalogued as rs543768371, COSV100589891; called by muse, mutect2, varscan2
- OR2T35 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as rs752074561, COSV58086405; called by muse, mutect2, varscan2
- OR8I2 | c.532del p.C178Vfs*7 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | catalogued as rs112181516, COSV56167552; called by mutect2, varscan2
- OTUD3 | c.554G>T p.S185I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100909039; called by muse, mutect2, varscan2
- OXLD1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs772084477, COSV100235746; called by muse, mutect2, varscan2
- OXSM | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as rs1210193181, COSV99772067; called by muse, mutect2, varscan2
- PALD1 | c.1809C>A p.C603* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as rs1163313217, COSV99698484; called by muse, mutect2, varscan2
- PAPOLA | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.036); catalogued as COSV53486269; called by muse, mutect2
- PARN | c.1177A>G p.M393V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV100421179; called by muse, mutect2, varscan2
- PAX1 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68273480; called by muse, mutect2, varscan2
- PAX7 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs866230294, COSV64752739; called by muse, mutect2, varscan2
- PAXIP1 | c.1130G>C p.S377T | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV101249907; called by muse, varscan2
- PCDHA3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV65369243; called by muse, mutect2, varscan2
- PCDHA3 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV63543574, COSV99061555; called by muse, mutect2, varscan2
- PCDHB2 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV99165828; called by muse, mutect2, varscan2
- PCDHGA8 | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.323); catalogued as rs1281710551, COSV53972133; called by muse, mutect2, varscan2
- PCDHGB1 | c.1413C>A p.S471R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.23); catalogued as COSV53940736, COSV99542469; called by muse, mutect2, varscan2
- PDCL2 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs775165131, COSV55259804, COSV55261512; called by muse, mutect2, varscan2
- PDE12 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100239918; called by muse, mutect2, varscan2
- PDGFRL | c.883G>T p.V295F | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99286551; called by muse, mutect2, varscan2
- PDZD2 | c.8018C>T p.S2673L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV99225864; called by muse, mutect2, varscan2
- PFKL | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1332071501, COSV62466439; called by muse, mutect2, varscan2
- PHF8 | c.1997C>T p.A666V (on ENST00000357988 / NM_001184896.1; = p.A630V on NM_015107.3) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV57681298; called by muse, mutect2, varscan2
- PHKA1 | c.1246-1G>A p.X416_splice | Splice Site (SNP) | VAF 23/52 reads (44%) | catalogued as COSV59806962, COSV59811288; called by muse, mutect2, varscan2
- PHKA2 | c.3070G>T p.G1024C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV101177267; called by muse, mutect2, varscan2
- PHRF1 | c.3857T>C p.M1286T (on ENST00000264555 / NM_001286581.2; = p.M1285T on NM_020901.4) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.304); catalogued as COSV99212581; called by muse, mutect2, varscan2
- PILRB | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs756431098, COSV100167154; called by muse, mutect2
- PLA2R1 | c.1027A>T p.S343C | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99323230; called by muse, varscan2
- PLB1 | c.595del p.V199Cfs*14 | Frame Shift Del (DEL) | VAF 22/45 reads (49%) | catalogued as COSV59828249; called by mutect2, pindel, varscan2
- PLCB2 | c.1721C>T p.S574L | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53035712; called by muse, mutect2, varscan2
- PLCG1 | c.3782G>A p.R1261H (on ENST00000373271 / NM_182811.2; = p.R1262H on NM_002660.3) | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs774703045, COSV54821358; called by muse, mutect2, varscan2
- PLEKHB2 | c.134A>T p.D45V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99301771; called by muse, mutect2, varscan2
- PLEKHG3 | c.2056C>A p.L686I (on ENST00000394691; = p.L742I on NM_001308147.2) | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99906834; called by muse, mutect2, varscan2
- PLOD3 | c.876dup p.Q293Afs*48 | Frame Shift Ins (INS) | VAF 18/48 reads (38%) | catalogued as rs746342377; called by mutect2, varscan2
- PLSCR3 | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100247973; called by muse, mutect2, varscan2
- PLVAP | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99391584, COSV99391754; called by muse, mutect2, varscan2
- PLXNA2 | c.528G>T p.E176D | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100885651; called by muse, mutect2, varscan2
- PLXNB1 | c.5025G>A p.M1675I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99603133; called by muse, mutect2, varscan2
- PM20D2 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99248448; called by muse, mutect2, varscan2
- PNCK | c.633del p.F212Sfs*14 (on ENST00000340888 / NM_001366975.1; = p.F295Sfs*14 on NM_001039582.3) | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as rs781891121, COSV61745231; called by mutect2, pindel, varscan2
- PNPLA5 | c.318del p.D107Tfs*14 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | catalogued as rs747771692; called by mutect2, pindel
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POR | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101203709, COSV67517158; called by muse, mutect2, varscan2
- POU3F4 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100937297; called by muse, mutect2, varscan2
- PPCS | c.612G>A p.Q204= | Splice Region (SNP) | VAF 25/53 reads (47%) | catalogued as COSV100999514; called by muse, mutect2, varscan2
- PPIP5K2 | c.3182C>T p.A1061V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.217); catalogued as rs782150216, COSV100383523; called by muse, mutect2, varscan2
- PPM1M | c.520G>A p.V174I (on ENST00000296487; = p.V335I on NM_144641.4) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs754393792, COSV99626300; called by muse, mutect2, varscan2
- PPP2CB | c.274T>C p.Y92H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV99646694; called by muse, mutect2, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 19/34 reads (56%) | catalogued as rs758484975; called by mutect2, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs540232176; called by mutect2, varscan2
- PRDM1 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.135); catalogued as COSV100958901, COSV64845112; called by muse, mutect2, varscan2
- PREX2 | c.4456G>C p.V1486L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99908596; called by muse, mutect2, varscan2
- PRICKLE1 | c.2315C>T p.S772L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1191261840, COSV58206381, COSV58211459; called by muse, mutect2, varscan2
- PRPF39 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | catalogued as rs1245586033, COSV99361068; called by muse, mutect2, varscan2
- PRPS2 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs752956171, COSV66179822, COSV66180377; called by muse, mutect2
- PRR12 | c.2429A>T p.Y810F (on ENST00000615927; = p.Y1631F on NM_020719.3) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV101330738; called by muse, mutect2, varscan2
- PRSS36 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.306); catalogued as COSV99191300; called by muse, mutect2, varscan2
- PRSS55 | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.228); catalogued as COSV100153841; called by muse, mutect2, varscan2
- PRUNE2 | c.7220G>A p.S2407N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs778291749, COSV100944874; called by muse, mutect2, varscan2
- PSD4 | c.2575G>A p.V859I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs766895686, COSV55527697; called by muse, mutect2, varscan2
- PSMD4 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.744); catalogued as rs751785323, COSV100924679; called by muse, mutect2, varscan2
- PTPN3 | c.2299C>T p.H767Y | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99356036; called by muse, mutect2, varscan2
- PTPRU | c.1855G>A p.G619S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1283282681, COSV100113289; called by muse, mutect2, varscan2
- PVRIG | c.236del p.G79Afs*245 | Frame Shift Del (DEL) | VAF 38/104 reads (37%) | catalogued as rs768997455; called by mutect2, pindel, varscan2
- RAB3GAP1 | c.902A>C p.D301A | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99921452; called by muse, mutect2, varscan2
- RAD23A | c.197T>C p.I66T | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100330893; called by muse, mutect2, varscan2
- RAD51C | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV99542853; called by muse, mutect2, varscan2
- RAF1 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.883); catalogued as COSV99312980; called by muse, mutect2, varscan2
- RAG2 | c.1524del p.G509Vfs*6 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | catalogued as COSV100271291, COSV57558940; called by mutect2, pindel, varscan2
- RASA1 | c.2921T>G p.L974R | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99170142; called by muse, mutect2, varscan2
- RBFOX1 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as rs139929599, CD139405; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBL1 | c.1225A>G p.S409G | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100727193; called by muse, mutect2, varscan2
- RBM25 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV99998787; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM28 | c.1675C>A p.L559I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99775802; called by muse, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as COSV56484832; called by mutect2, varscan2
- RC3H2 | c.3381-2A>G p.X1127_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100605831; called by muse, mutect2, varscan2
- RDH5 | c.718del p.A240Pfs*7 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs753378940, CM991095; called by mutect2, pindel, varscan2
- RELN | c.1582A>G p.N528D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV100634271; called by muse, mutect2, varscan2
- REXO1 | c.3230C>T p.T1077M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1282888676, COSV99402503; called by muse, mutect2, varscan2
- RFC1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs201358782; called by muse, mutect2, varscan2
- RFXANK | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 22/33 reads (67%) | catalogued as rs747402973, CM033006, COSV57393386; called by muse, mutect2, varscan2
- RHPN2 | c.368T>G p.V123G | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV99577962; called by muse, mutect2, varscan2
- RIC1 | c.2068C>T p.Q690* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99317653; called by muse, mutect2, varscan2
- RIF1 | c.5162A>C p.K1721T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54620248, COSV99690893; called by muse, mutect2, varscan2
- RIMBP2 | c.1774del p.H592Tfs*11 | Frame Shift Del (DEL) | VAF 15/30 reads (50%) | catalogued as rs759334405; called by mutect2, pindel, varscan2
- RIPK3 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.75); PolyPhen benign (0.142); catalogued as COSV99353330; called by muse, mutect2, varscan2
- RNF138 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as rs1363216536, COSV55233729; called by muse, mutect2, varscan2
- RNF213 | c.6266G>A p.R2089Q | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs760169991, COSV60399406; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 34/55 reads (62%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNH1 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1288608971, COSV62250980; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRD2 | c.697A>G p.K233E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV100954736; called by muse, mutect2, varscan2
- RSPH10B2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as rs746889216, COSV51870264; called by muse, mutect2, varscan2
- RUBCN | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs753948060, COSV56363933, COSV99584320; called by muse, mutect2, varscan2
- RUNDC1 | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as rs765805859, COSV100865870; called by muse, mutect2, varscan2
- RUNX1T1 | c.608C>T p.A203V (on ENST00000265814 / NM_001198628.1; = p.A176V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV99753445; called by muse, mutect2, varscan2
- RUSC2 | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.644); catalogued as rs367899388; called by muse, mutect2, varscan2
- RYR2 | c.9961C>T p.P3321S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99053374; called by muse, mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs765867975; called by mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 33/85 reads (39%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCD | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV100948907; called by muse, mutect2, varscan2
- SCN1A | c.2926A>G p.M976V (on ENST00000303395 / NM_001202435.3; = p.M965V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV100319201; called by muse, mutect2, varscan2
- SCN9A | c.5157del p.V1720Ffs*33 (on ENST00000303354; = p.V1709Ffs*33 on NM_002977.3) | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as rs1027061303; called by mutect2, varscan2
- SCUBE3 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99234851; called by muse, mutect2, varscan2
- SCUBE3 | c.2510del p.P837Hfs*27 | Frame Shift Del (DEL) | VAF 30/67 reads (45%) | catalogued as rs765256475; called by mutect2, pindel, varscan2
- SDF2 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761041365, COSV99897962; called by muse, mutect2, varscan2
- SEC23B | c.736_738del p.L246del | In Frame Del (DEL) | VAF 24/65 reads (37%) | catalogued as rs746666686; called by pindel, varscan2
- SECISBP2L | c.2036A>G p.N679S (on ENST00000559471 / NM_001193489.2; = p.N634S on NM_014701.4) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.757); catalogued as COSV99960684; called by muse, mutect2, varscan2
- SELENOO | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV99955971; called by muse, mutect2, varscan2
- SEMA5B | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99532545; called by muse, mutect2, varscan2
- SENP2 | c.961C>A p.L321I | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as COSV99957999; called by muse, mutect2, varscan2
- SENP5 | c.1585T>A p.L529I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100052129; called by muse, mutect2, varscan2
- SEPHS1 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100525944; called by muse, mutect2, varscan2
- SEPTIN4 | c.575G>A p.R192K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.088); catalogued as COSV58727703; called by muse, mutect2, varscan2
- SEPTIN7 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV100621831, COSV100621859, COSV63255040; called by muse, mutect2, varscan2
- SERPINA1 | c.530C>A p.A177D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100872155; called by muse, mutect2, varscan2
- SERPINA12 | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100369753; called by muse, varscan2
- SERPINA3 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs777232494, COSV101261759; called by muse, mutect2, varscan2
- SERPINB4 | c.668T>C p.L223S | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1445978459; called by muse, mutect2
- SERPINC1 | c.119G>A p.C40Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100875093; called by muse, mutect2, varscan2
- SETDB1 | c.2124C>A p.S708R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99645356; called by muse, mutect2, varscan2
- SEZ6L | c.2212G>T p.E738* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV50665138, COSV99962528; called by muse, mutect2, varscan2
- SEZ6L2 | c.2536G>A p.A846T (on ENST00000308713 / NM_001114099.3; = p.A789T on NM_012410.4) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1262681210, COSV100435635; called by muse, mutect2, varscan2
- SFMBT2 | c.2585C>T p.T862M | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1372292706, COSV62819041; called by muse, mutect2, varscan2
- SGMS1 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV62369191, COSV62370392, COSV62374188; called by muse, mutect2
- SH3RF3 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs141684240, COSV100512458; called by muse, mutect2, varscan2
- SHANK2 | c.5422A>G p.M1808V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV99575158; called by muse, mutect2, varscan2
- SHROOM2 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs773234401, COSV101098891; called by muse, mutect2, varscan2
- SIPA1L3 | c.1265A>G p.D422G | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV99729623; called by muse, mutect2, varscan2
- SKIDA1 | c.2547T>G p.N849K | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101481327; called by muse, mutect2
- SLAMF8 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs534230763, COSV56989929; called by muse, mutect2, varscan2
- SLC10A3 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as rs782319797, COSV99682173; called by muse, mutect2, varscan2
- SLC12A4 | c.3191C>T p.T1064I | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV99863163; called by muse, mutect2, varscan2
- SLC17A9 | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs776491064, COSV100947916; called by muse, mutect2, varscan2
- SLC19A1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264646995, COSV100229507; called by muse, mutect2, varscan2
- SLC22A25 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100123776; called by muse, mutect2, varscan2
- SLC25A12 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs369666236; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A13 | c.1441G>T p.G481W | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55710921, COSV99673901; called by muse, mutect2, varscan2
- SLC25A34 | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99606711; called by muse, mutect2, varscan2
- SLC27A3 | c.319_322del p.K107Efs*16 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs866877278; called by mutect2, pindel, varscan2
- SLC2A7 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV101280813; called by muse, mutect2, varscan2
- SLC35F5 | c.742del p.C248Afs*22 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs577214214; called by mutect2, varscan2
- SLC6A6 | c.1348-1G>T p.X450_splice | Splice Site (SNP) | VAF 27/62 reads (44%) | catalogued as COSV100692327; called by muse, mutect2, varscan2
- SLITRK3 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.968); catalogued as rs748255702, COSV53850089; called by muse, mutect2, varscan2
- SLX4 | c.4109G>A p.S1370N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as rs747599109, COSV99568312; called by muse, mutect2, varscan2
- SMARCA1 | c.2978G>A p.R993Q | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64410695, COSV64411340; called by muse, mutect2, varscan2
- SMUG1 | c.614T>C p.L205P | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99679488; called by muse, mutect2, varscan2
- SNUPN | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780050678, COSV100419436; called by muse, mutect2, varscan2
- SPACA1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.033); catalogued as rs912384960, COSV99389548; called by muse, mutect2, varscan2
- SPAG5 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs771844176, COSV58803257; called by muse, mutect2, varscan2
- SPEG | c.9734A>G p.Q3245R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV100405095; called by muse, mutect2, varscan2
- SPRTN | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs140605242; called by muse, mutect2, varscan2
- SPTA1 | c.2218C>T p.Q740* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100935247, COSV100935507; called by mutect2, varscan2
- SPTBN5 | c.6374C>A p.P2125H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100311855; called by mutect2, varscan2
- SREBF2 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs200228342, COSV100761496; called by muse, mutect2, varscan2
- SRP72 | c.25del p.V9Cfs*10 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs763130641; called by mutect2, varscan2
- ST8SIA5 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | PolyPhen probably damaging (0.94); catalogued as rs749600014, COSV59331566; called by muse, mutect2, varscan2
- STAU2 | c.871C>T p.R291C (on ENST00000524300 / NM_001164380.2; = p.R259C on NM_014393.2) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs757844080, COSV63307217; called by muse, mutect2, varscan2
- STK31 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs774334183, COSV63456421; called by muse, mutect2, varscan2
- STRADA | c.997del p.R333Gfs*42 (on ENST00000336174 / NM_001363786.1; = p.R296Gfs*58 on NM_153335.6) | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | catalogued as rs762120842, COSV51992441; called by mutect2, varscan2
- SULF2 | c.1736G>T p.G579V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.082); catalogued as rs770162661, COSV100737290; called by mutect2, varscan2
- SYNE1 | c.24977-2_24977-1insT p.X8326_splice (on ENST00000367255 / NM_182961.4; = p.X8278_splice on NM_033071.3) | Splice Site (INS) | VAF 13/43 reads (30%) | catalogued as COSV99572486; called by mutect2, pindel, varscan2
- SYNE2 | c.80-1G>A p.X27_splice | Splice Site (SNP) | VAF 36/81 reads (44%) | catalogued as COSV100420294; called by muse, mutect2, varscan2
- TACC2 | c.6974C>A p.P2325H (on ENST00000334433; = p.P403H on NM_006997.4) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99587379, COSV99587941; called by muse, mutect2, varscan2
- TAF1C | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100499712; called by muse, mutect2, varscan2
- TBC1D23 | c.1876C>T p.R626W (on ENST00000394144 / NM_001199198.3; = p.R611W on NM_018309.5) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1317132696, COSV100792628; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs758822980; called by mutect2, varscan2
- TCIM | c.271A>G p.K91E | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100249638; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs763321097; called by mutect2, varscan2
- TEK | c.2644C>T p.H882Y | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101193492; called by muse, mutect2, varscan2
- TEKT3 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs761794041, COSV100107196, COSV99060495; called by muse, mutect2, varscan2
- TENM2 | c.4349C>T p.A1450V (on ENST00000518659 / NM_001122679.2; = p.A1211V on NM_001080428.3) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754822894, COSV69129432; called by muse, mutect2, varscan2
- TFEB | c.943C>A p.R315S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100026341, COSV57826912; called by muse, mutect2, varscan2
- TG | c.3836G>A p.R1279Q | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs546423640, COSV99602128; called by muse, varscan2
- THAP6 | c.629A>G p.D210G | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV100293124; called by muse, mutect2, varscan2
- THAP9 | c.1023dup p.V342Cfs*19 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs758965702; called by mutect2, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 23/58 reads (40%) | catalogued as COSV50235787; called by mutect2, pindel, varscan2
- TMEM108 | c.222del p.S75Hfs*30 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as COSV58866283; called by mutect2, pindel, varscan2
- TMEM127 | c.677T>A p.V226D | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV99302683; called by muse, mutect2, varscan2
- TMEM130 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs782385656, COSV100228880; called by muse, mutect2, varscan2
- TMEM132B | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs750662543, COSV54773276; called by muse, mutect2, varscan2
- TMEM132D | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757474690, COSV101398995, COSV70623917; called by muse, mutect2, varscan2
- TMEM139 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs202131612, COSV60081687; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 34/40 reads (85%) | catalogued as rs749773249; called by mutect2, varscan2
- TMPRSS4 | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101449413; called by muse, mutect2, varscan2
- TNFRSF10A | c.491G>A p.C164Y | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99646285; called by muse, mutect2, varscan2
- TOPBP1 | c.4102C>T p.R1368* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as COSV99605579; called by muse, mutect2, varscan2
- TPCN1 | c.907T>C p.Y303H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100136904; called by muse, mutect2, varscan2
- TPST1 | c.1028T>G p.I343S | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100507232; called by muse, mutect2, varscan2
- TRIM62 | c.1070T>C p.V357A | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99357878; called by muse, mutect2, varscan2
- TRIM65 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs750895177, COSV99485471; called by muse, mutect2, varscan2
- TSC1 | c.1271_1272del p.R424Nfs*17 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs118203509; called by pindel, varscan2
- TSC22D1 | c.3146del p.P1049Lfs*38 (on ENST00000458659 / NM_183422.4; = p.P120Lfs*38 on NM_006022.4) | Frame Shift Del (DEL) | VAF 12/25 reads (48%) | catalogued as rs762485832; called by mutect2, pindel, varscan2
- TSKS | c.1748del p.P583Qfs*? | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as rs749002253, COSV55877613; called by mutect2, pindel, varscan2
- TTC19 | c.773G>T p.R258M | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV51972239; called by muse, mutect2, varscan2
- TTC37 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs1033302823, COSV62453770; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL1 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99840468; called by muse, mutect2, varscan2
- TUBGCP6 | c.3545G>A p.R1182Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as rs749106188, COSV99955975; called by muse, mutect2, varscan2
- U2AF1L4 | c.451C>T p.R151W (on ENST00000412391; = p.R112W on NM_001040425.3) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53073864; called by muse, mutect2
- UBTD1 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53967501; called by muse, mutect2, varscan2
- UNC13C | c.5810C>T p.T1937I | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV99520610; called by muse, mutect2, varscan2
- UNC5A | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746986911, COSV99994846; called by muse, mutect2, varscan2
- UNC93A | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV100023485; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs767420916; called by mutect2, varscan2
- UROD | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV55800219; called by muse, mutect2, varscan2
- USP36 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.173); catalogued as rs1441981836, COSV100361659; called by muse, mutect2, varscan2
- UTP20 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99882076; called by muse, mutect2, varscan2
- UTP20 | c.954G>T p.Q318H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV99882078; called by muse, varscan2
- UTP20 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as rs765120524, COSV55371548; called by muse, mutect2, varscan2
- VAC14 | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs145401972; called by muse, mutect2, varscan2
- VAV2 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100895978; called by muse, mutect2, varscan2
- VEPH1 | c.1661del p.N554Tfs*5 | Frame Shift Del (DEL) | VAF 19/38 reads (50%) | catalogued as rs756863093; called by mutect2, varscan2
- VRTN | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV99832343; called by muse, mutect2, varscan2
- VWF | c.3292G>A p.A1098T | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs755385279, COSV54615380; called by muse, mutect2, varscan2
- WDHD1 | c.1535A>G p.H512R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.124); catalogued as COSV100777619; called by muse, mutect2, varscan2
- WDR47 | c.1831G>A p.A611T (on ENST00000369962 / NM_001142551.2; = p.A612T on NM_014969.5) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs925679084, COSV100728394; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs746919573; called by mutect2, varscan2
- WDR70 | c.1416G>A p.A472= | Splice Region (SNP) | VAF 21/47 reads (45%) | catalogued as rs751354291, COSV54282799; called by muse, mutect2, varscan2
- WLS | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775625231, COSV52037040; called by muse, mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 11/15 reads (73%) | catalogued as rs771899177; called by mutect2, varscan2
- WWC3 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs745880432, COSV66501265; called by muse, mutect2, varscan2
- XRCC3 | c.755C>A p.P252H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100572859; called by muse, mutect2, varscan2
- YARS1 | c.793A>G p.K265E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.213); catalogued as COSV100993464; called by muse, mutect2, varscan2
- YWHAE | c.66A>G p.E22= | Splice Region (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99981387; called by muse, mutect2, varscan2
- YWHAQ | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs371354151; called by muse, varscan2
- ZBTB47 | c.1540G>A p.G514S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as rs184233362, COSV51766630; called by muse, varscan2
- ZC3H4 | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754139171, COSV53412831; called by muse, mutect2, varscan2
- ZC3H7A | c.1536G>T p.E512D | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100865560; called by muse, mutect2, varscan2
- ZCRB1 | c.552del p.K184Nfs*20 | Frame Shift Del (DEL) | VAF 42/97 reads (43%) | catalogued as rs751992496; called by mutect2, varscan2
- ZDHHC20 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV100203640; called by muse, mutect2, varscan2
- ZDHHC23 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs372445676; called by muse, mutect2, varscan2
- ZDHHC6 | c.119T>A p.I40N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.36); catalogued as COSV101024424; called by muse, mutect2, varscan2
- ZFHX4 | c.4616G>A p.R1539H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs981659626, COSV50703705; called by muse, mutect2, varscan2
- ZFR | c.1074del p.E359Kfs*4 | Frame Shift Del (DEL) | VAF 51/110 reads (46%) | catalogued as rs751974853; called by mutect2, varscan2
- ZIC4 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs373361660, COSV101268063; called by muse, mutect2, varscan2
- ZNF205 | c.1463G>A p.S488N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV99530514; called by muse, mutect2, varscan2
- ZNF226 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100335196; called by muse, mutect2, varscan2
- ZNF264 | c.1694del p.N565Ifs*5 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | catalogued as rs1568477500; called by mutect2, pindel, varscan2
- ZNF589 | c.418del p.A140Lfs*25 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs764544661; called by mutect2, pindel, varscan2
- ZNF655 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV99402251; called by muse, mutect2, varscan2
- ZNF665 | c.1396A>G p.I466V (on ENST00000600412; = p.I531V on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1369590210, COSV101128669; called by muse, mutect2, varscan2
- ZNF672 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs779614072, COSV100129291; called by muse, mutect2, varscan2
- ZNF680 | c.934C>A p.H312N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100549084, COSV100549257; called by muse, mutect2, varscan2
- ZNF750 | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.164); catalogued as rs1404974378, COSV99489850; called by muse, mutect2, varscan2
- ZNF750 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as COSV53961811; called by muse, mutect2, varscan2
- ZNF862 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs760393168, COSV99783639; called by muse, mutect2, varscan2
- ZNRF3 | c.989G>A p.C330Y (on ENST00000544604 / NM_001206998.2; = p.C230Y on NM_032173.3) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60433674; called by muse, mutect2, varscan2
- ZZEF1 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs764501492, COSV101067927; called by muse, mutect2, varscan2
- ABO | c.801del p.F268Sfs*20 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- ACTRT2 | c.984del p.I329Sfs*23 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- ADAMTS1 | c.2791del p.R931Efs*3 | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | called by mutect2, varscan2
- ALPG | c.839_853del p.S280_M285delinsL | In Frame Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, varscan2
- ANK3 | c.12059del p.K4020Rfs*45 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | called by mutect2, pindel, varscan2
- ANK3 | c.9993del p.K3331Nfs*6 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | called by mutect2, pindel
- ANK3 | c.3290dup p.N1097Kfs*2 (on ENST00000280772 / NM_001320874.2; = p.N231Kfs*2 on NM_001149.3) | Frame Shift Ins (INS) | VAF 21/50 reads (42%) | called by mutect2, pindel, varscan2
- ARHGDIB | c.211del p.R71Gfs*31 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 25/54 reads (46%) | called by mutect2, pindel, varscan2
- ATP13A3 | c.1426del p.I476Sfs*11 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, pindel, varscan2
- B3GLCT | c.238del p.S80Afs*3 | Frame Shift Del (DEL) | VAF 28/50 reads (56%) | called by mutect2, varscan2
- BCOR | c.4811_4812del p.S1604Cfs*3 (on ENST00000378444 / NM_001123385.2; = p.S1570Cfs*3 on NM_017745.6) | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by pindel, varscan2
- BRD3 | c.73del p.E25Rfs*23 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- CALHM5 | c.738del p.F246Lfs*75 | Frame Shift Del (DEL) | VAF 27/64 reads (42%) | called by mutect2, varscan2
- CCDC33 | c.1059del p.T354Qfs*18 | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | called by mutect2, pindel, varscan2
- CD5 | c.1279+3_1279+6del p.X427_splice | Splice Site (DEL) | VAF 18/42 reads (43%) | called by mutect2, pindel, varscan2
- CDK11A | c.493C>T p.R165W (on ENST00000378633 / NM_001313896.2; = p.R175W on NM_024011.4) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- CFAP92 | c.781dup p.T261Nfs*24 | Frame Shift Ins (INS) | VAF 44/116 reads (38%) | called by mutect2, pindel, varscan2
- CLCN3 | c.2394del p.D799Ifs*17 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- CLOCK | c.1105_1107del p.I369del | In Frame Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- CNN1 | c.512dup p.N171Kfs*113 | Frame Shift Ins (INS) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- COQ8A | c.1357del p.L453Wfs*24 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- DBF4 | c.74del p.N25Tfs*5 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- DCLK1 | c.1574G>A p.G525D | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- DENND5B | c.2141del p.N714Tfs*2 | Frame Shift Del (DEL) | VAF 29/68 reads (43%) | called by mutect2, pindel, varscan2
- DGKZ | c.199dup p.A67Gfs*24 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | called by mutect2, pindel, varscan2
- DSG2 | c.375del p.L126Cfs*2 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel, varscan2
- E4F1 | c.2148del p.E717Rfs*3 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- ECM2 | c.1130del p.N377Ifs*8 | Frame Shift Del (DEL) | VAF 21/51 reads (41%) | called by mutect2, pindel, varscan2
- EEF2 | c.2340del p.M781Cfs*20 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- ENGASE | c.1002del p.N336Tfs*15 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | called by mutect2, pindel, varscan2
- EPN2 | c.965dup p.K323Efs*39 | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- EVL | c.915del p.S306Lfs*59 (on ENST00000402714 / NM_001330221.2; = p.S308Lfs*59 on NM_016337.3) | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- FAT1 | c.4089del p.F1363Lfs*5 | Frame Shift Del (DEL) | VAF 8/11 reads (73%) | called by mutect2, varscan2
- FBXO6 | c.702dup p.G235Wfs*102 | Frame Shift Ins (INS) | VAF 11/24 reads (46%) | called by mutect2, pindel, varscan2
- FLG2 | c.1965dup p.G656Wfs*30 | Frame Shift Ins (INS) | VAF 49/168 reads (29%) | called by mutect2, pindel, varscan2
- FOLR1 | c.407_408del p.K136Rfs*4 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | called by mutect2, pindel, varscan2
- FOXP1 | c.209_211del p.L70del | In Frame Del (DEL) | VAF 11/36 reads (31%) | called by pindel, varscan2
- HDAC2 | c.1375del p.T459Qfs*47 | Frame Shift Del (DEL) | VAF 36/93 reads (39%) | called by mutect2, pindel, varscan2
- HMCN1 | c.1000dup p.T334Nfs*25 | Frame Shift Ins (INS) | VAF 16/66 reads (24%) | called by mutect2, varscan2
- HOXA3 | c.813del p.G272Efs*6 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- IGHV3-16 | c.53A>G p.Q18R | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- IGSF9 | c.1021del p.V341* (on ENST00000368094 / NM_001135050.2; = p.V325* on NM_020789.4) | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- IKZF5 | c.15del p.K5Nfs*8 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | called by mutect2, varscan2
- INTS8 | c.1471_1472del p.C491Hfs*2 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | called by pindel, varscan2
- ISG15 | c.415del p.E139Sfs*7 | Frame Shift Del (DEL) | VAF 29/85 reads (34%) | called by mutect2, pindel, varscan2
- ITGAE | c.1669-1G>T p.X557_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 37/43 reads (86%) | called by mutect2, varscan2
- JPH2 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- JUNB | c.344del p.G115Vfs*35 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | called by mutect2, pindel, varscan2
- KCNMA1 | c.2076del p.K692Nfs*15 (on ENST00000286628 / NM_001161352.2; = p.K692Nfs*36 on NM_002247.4) | Frame Shift Del (DEL) | VAF 30/72 reads (42%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.14680dup p.S4894Kfs*7 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | called by mutect2, pindel, varscan2
- KIAA1549 | c.5205del p.S1736Pfs*21 | Frame Shift Del (DEL) | VAF 41/111 reads (37%) | called by mutect2, pindel, varscan2
- KIF27 | c.3722-3del | Splice Region (DEL) | VAF 8/19 reads (42%) | called by mutect2, pindel, varscan2
- KRT222 | c.121del p.M41Wfs*8 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- LIG4 | c.1179del p.F393Lfs*8 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- LRRC41 | c.1034del p.P345Qfs*44 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | called by mutect2, pindel, varscan2
- MAGEC1 | c.1714del p.E572Rfs*58 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- MAPKBP1 | c.3446del p.P1149Rfs*186 (on ENST00000456763 / NM_001128608.2; = p.P1143Rfs*186 on NM_014994.3) | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- MIER1 | c.612del p.V205Yfs*20 (on ENST00000355356 / NM_001077701.3; = p.V222Yfs*20 on NM_020948.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by pindel, varscan2
- MYO15A | c.4670dup p.V1558Gfs*44 | Frame Shift Ins (INS) | VAF 10/21 reads (48%) | called by mutect2, varscan2
- NAT16 | c.215del p.G72Afs*33 | Frame Shift Del (DEL) | VAF 45/119 reads (38%) | called by mutect2, pindel, varscan2
- NCOR2 | c.5821del p.R1941Gfs*41 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- NHS | c.3448dup p.T1150Nfs*9 | Frame Shift Ins (INS) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- NIPBL | c.1697del p.K566Sfs*48 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- NOS1 | c.149del p.G50Afs*26 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- OR6C4 | c.*4del | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- PAN2 | c.468_470del p.E156del | In Frame Del (DEL) | VAF 12/23 reads (52%) | called by mutect2, pindel, varscan2
- PCDHAC2 | c.1864del p.Y622Tfs*3 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- PLA2R1 | c.1068del p.K356Nfs*3 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by pindel, varscan2
- PLEC | c.13370del p.G4457Afs*55 (on ENST00000322810 / NM_201380.4; = p.G4347Afs*55 on NM_000445.5) | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, varscan2
- PLOD2 | c.583del p.Y195Tfs*9 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- POLR1A | c.1798del p.Q600Rfs*31 | Frame Shift Del (DEL) | VAF 15/35 reads (43%) | called by mutect2, pindel, varscan2
- PRKDC | c.10814del p.N3605Tfs*48 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by mutect2, varscan2
- PRPF4B | c.2678C>T p.T893I | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- PRUNE2 | c.3431del p.G1144Vfs*26 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, varscan2
- PTPRH | c.36del p.N13Tfs*24 | Frame Shift Del (DEL) | VAF 26/58 reads (45%) | called by mutect2, pindel, varscan2
- RAB20 | c.217del p.A73Rfs*10 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- RGS21 | c.441del p.K147Nfs*12 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- RNASET2 | c.108dup p.L37Tfs*9 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- RPL10L | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- SEL1L3 | c.2234dup p.N746Efs*79 | Frame Shift Ins (INS) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- SHANK1 | c.4823del p.P1608Rfs*17 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- SLC2A8 | c.1197_1198del p.E399Dfs*62 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | called by pindel, varscan2
- SNRPA | c.386del p.G129Efs*19 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | called by mutect2, pindel, varscan2
- SOAT1 | c.1154del p.L385Cfs*66 | Frame Shift Del (DEL) | VAF 29/99 reads (29%) | called by mutect2, pindel, varscan2
- SPATA31E1 | c.74del p.P25Qfs*25 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | called by mutect2, pindel, varscan2
- SRGAP3 | c.2548del p.V850* | Frame Shift Del (DEL) | VAF 8/10 reads (80%) | called by mutect2, varscan2
- SSH3 | c.1003del p.H335Tfs*25 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- STAT3 | c.296del p.M99Rfs*39 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | called by mutect2, pindel, varscan2
- SYTL2 | c.1986del p.K662Nfs*8 (on ENST00000528231 / NM_001162951.2; = p.K638Nfs*8 on NM_032943.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/77 reads (44%) | called by mutect2, pindel, varscan2
- TENM1 | c.632del p.P211Lfs*11 | Frame Shift Del (DEL) | VAF 35/86 reads (41%) | called by mutect2, pindel, varscan2
- TKFC | c.1474dup p.D492Gfs*24 | Frame Shift Ins (INS) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- TMEM38B | c.286del p.C96Afs*5 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- TMEM87A | c.152del p.N51Ifs*17 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | called by mutect2, pindel, varscan2
- TNFRSF11A | c.1395del p.K465Nfs*61 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- TNRC6C | c.1473dup p.K492Efs*56 | Frame Shift Ins (INS) | VAF 8/15 reads (53%) | called by mutect2, pindel, varscan2
- TPCN2 | c.347dup p.P117Sfs*66 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- TRIM55 | c.1089_1092del p.T364Sfs*46 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- TRPM6 | c.823_824del p.L275Afs*42 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | called by pindel, varscan2
- UBR1 | c.4745dup p.N1582Kfs*8 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- UNC5C | c.1471del p.Q491Kfs*15 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- USO1 | c.725dup p.N242Kfs*10 | Frame Shift Ins (INS) | VAF 31/84 reads (37%) | called by mutect2, pindel, varscan2
- USP6NL | c.1255dup p.Q419Pfs*26 | Frame Shift Ins (INS) | VAF 18/41 reads (44%) | called by mutect2, pindel, varscan2
- VIRMA | c.4096del p.S1366Vfs*3 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- WDR72 | c.2332del p.M778Cfs*9 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | called by mutect2, pindel, varscan2
- WRAP53 | c.910del p.S304Pfs*28 | Frame Shift Del (DEL) | VAF 32/84 reads (38%) | called by mutect2, pindel, varscan2
- WWC2 | c.616del p.M206Cfs*17 | Frame Shift Del (DEL) | VAF 12/25 reads (48%) | called by mutect2, pindel, varscan2
- ZBED4 | c.375del p.F125Lfs*16 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- ZBTB5 | c.387del p.S130Vfs*22 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- ZNF544 | c.719del p.N240Tfs*27 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- ACSM1 | c.138G>A p.P46= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs766453598, COSV54634493, COSV99532852; called by muse, mutect2, varscan2
- ADCY6 | c.2796G>T p.G932= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100326764; called by muse, mutect2, varscan2
- AGO1 | c.54G>A p.Q18= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV100940883; called by muse, mutect2, varscan2
- AIPL1 | c.999G>A p.Q333= | Silent (SNP) | VAF 108/260 reads (42%) | catalogued as COSV100006147; called by muse, mutect2, varscan2
- ANGPT4 | c.1101G>A p.V367= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs769668731, COSV101124818; called by muse, mutect2, varscan2
- ANKRD36 | c.363C>T p.G121= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as rs778341904, COSV101347442; called by muse, mutect2, varscan2
- ANO10 | c.1704C>T p.V568= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV99428758; called by muse, mutect2, varscan2
- ANO5 | c.2631T>C p.H877= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100202032; called by muse, mutect2, varscan2
- AP5Z1 | c.1407G>A p.A469= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs757042274, COSV100804191; called by muse, mutect2
- ARAP1 | c.2494C>T p.L832= (on ENST00000393609 / NM_001040118.2; = p.L587= on NM_015242.4) | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs1314896787, COSV100502049; called by muse, mutect2, varscan2
- ARMC6 | c.123C>T p.R41= (on ENST00000392336; = p.R16= on NM_033415.4) | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs769945048, COSV99523097; called by muse, mutect2, varscan2
- ARNT2 | c.1374G>A p.S458= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1295252545, COSV57583915; ClinVar: likely benign; called by muse, mutect2, varscan2
- ASB10 | c.459C>T p.H153= (on ENST00000420175 / NM_001142459.2; = p.H138= on NM_080871.4) | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs752454521, COSV99318785; called by muse, mutect2, varscan2
- BAZ1B | c.3813G>A p.E1271= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100289922; called by muse, mutect2, varscan2
- BCL6B | c.348C>A p.T116= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV99546789; called by muse, mutect2, varscan2
- BHMT2 | c.732G>A p.A244= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs767577205, COSV54873318; called by muse, mutect2, varscan2
- C1orf56 | c.607C>T p.L203= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99764733; called by muse, mutect2
- C2orf16 | c.219C>T p.S73= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs371386242; called by muse, mutect2, varscan2
- CA10 | c.549T>C p.S183= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as COSV99564032; called by muse, mutect2, varscan2
- CALU | c.246C>T p.G82= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs1437131408, COSV99975715; called by muse, mutect2, varscan2
- CAMK1 | c.1035G>A p.P345= | Silent (SNP) | VAF 39/70 reads (56%) | catalogued as rs867535337, COSV99844847; called by muse, mutect2, varscan2
- CAPNS1 | c.141C>T p.G47= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs17879825; called by muse, varscan2
- CD93 | c.880C>T p.L294= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV99849387; called by muse, mutect2
- CDHR2 | c.3870C>T p.G1290= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs140266714; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2256G>A p.T752= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs773050443, COSV100575577; called by muse, mutect2, varscan2
- CEL | c.294C>T p.Y98= (on ENST00000673714; = p.Y95= on NM_001807.6) | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs531669054, COSV100672639; called by mutect2, varscan2
- CENPE | c.891A>G p.G297= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99478542; called by muse, mutect2, varscan2
- CEP170 | c.1131G>A p.T377= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as rs766093606, COSV100317493; called by muse, mutect2, varscan2
- CHD2 | c.5391C>T p.H1797= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs755395580, COSV101245653; called by muse, mutect2, varscan2
- CHRM4 | c.1371C>T p.N457= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as rs772700324, COSV100551358; called by muse, mutect2, varscan2
- CKAP2 | c.1968G>A p.T656= (on ENST00000378037 / NM_001098525.2; = p.T655= on NM_018204.5) | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs754490339, COSV99318278; called by muse, mutect2, varscan2
- CNOT11 | c.1192C>T p.L398= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs958582221, COSV99179285, COSV99179340; called by muse, mutect2, varscan2
- CNTN6 | c.2184G>A p.L728= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100611337; called by muse, mutect2, varscan2
- COASY | c.1497C>T p.R499= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99888592; called by muse, mutect2, varscan2
- COL18A1 | c.2694G>A p.L898= (on ENST00000359759 / NM_130444.3; = p.L663= on NM_030582.4) | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV100700807, COSV62698090; called by muse, mutect2, varscan2
- COL4A2 | c.5061G>A p.S1687= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs772402884, COSV100847421; called by muse, mutect2, varscan2
- CRACDL | c.2469G>A p.A823= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs765707391, COSV67407176; called by muse, mutect2, varscan2
- CRACR2A | c.459C>T p.G153= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs754763063, COSV52911506; called by muse, mutect2, varscan2
- CREBBP | c.6342C>T p.G2114= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV52128649; called by muse, mutect2, varscan2
- CRIM1 | c.1257C>T p.D419= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs775691814, COSV99753894; called by muse, mutect2, varscan2
- CSTF2 | c.1176A>G p.L392= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100880807; called by mutect2, varscan2
- CUX1 | c.2544C>T p.G848= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs373275150; called by muse, mutect2, varscan2
- DISP2 | c.4029G>A p.A1343= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs769056239, COSV51137452, COSV51140382; called by muse, mutect2, varscan2
- DNAH17 | c.5409C>T p.C1803= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs370045140; called by muse, mutect2, varscan2
- DNAH17 | c.3771C>G p.G1257= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV101102886, COSV67760774; called by muse, mutect2, varscan2
- DNAJC10 | c.1374T>C p.L458= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV99899445; called by muse, mutect2, varscan2
- DSG1 | c.129A>G p.S43= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs753543956, COSV99936259; called by muse, mutect2, varscan2
- DSG2 | c.1827C>T p.G609= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99853324; called by muse, mutect2, varscan2
- DSG2 | c.2340G>A p.A780= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs375539435, COSV99853325; called by muse, mutect2, varscan2
- DTX2 | c.717G>A p.G239= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs1467187399, COSV100184726; called by muse, varscan2
- DYNC2H1 | c.8775T>C p.L2925= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV100519117; called by muse, mutect2, varscan2
- EBF2 | c.396G>A p.S132= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs757373103, COSV68777828; called by muse, mutect2, varscan2
- EIF5AL1 | c.159C>T p.H53= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs1379612668, COSV101592809; called by muse, mutect2, varscan2
165 further variants in this file (0 protein-altering or splice-affecting, 144 silent, 21 other) are not listed here.
